Somatic mutation profile of tumor specimen TARGET-10-PARWDM-09B (aliquot TARGET-10-PARWDM-09B-01D) from TARGET case TARGET-10-PARWDM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,814 days).
Specimen TARGET-10-PARWDM-09B: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 264225ee-a6fa-4f7b-b585-0eb6f1fc4ed1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARWDM-10B (Blood Derived Normal), aliquot TARGET-10-PARWDM-10B-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9d88e68-0055-406e-a678-18979573b4b3

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Intron 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 4/32 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADORA2B | c.682C>T p.R228W | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as rs78982650, COSV58483258; called by muse, mutect2, varscan2
- ALDOC | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs762828594, COSV52027216; called by muse, mutect2, varscan2
- CMTM1 | c.20A>G p.K7R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.023); catalogued as COSV50451892; called by muse, mutect2
- DISP3 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1404234836, COSV53826028; called by muse, mutect2, varscan2
- GANAB | c.1955_1956insAGC p.F652delinsLA | In Frame Ins (INS) | VAF 5/21 reads (24%) | catalogued as COSV60469907; called by mutect2, pindel, varscan2
- IQUB | c.201C>A p.S67R | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as COSV61243720; called by muse, mutect2, varscan2
- MED18 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1379626555; called by muse, mutect2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- PPP2R5B | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as COSV51214513; called by muse, mutect2, varscan2
- SLCO6A1 | c.287G>T p.S96I | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV65806022; called by muse, mutect2, varscan2
- VPS13B | c.8252G>A p.G2751D | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.356); catalogued as rs376283724; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPEP2 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- GRM3 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.02); called by muse, mutect2
- C1orf167 | c.4170C>T p.D1390= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs562859148, COSV100453416; called by muse, mutect2, varscan2
- ECHS1 | c.171C>T p.A57= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ELANE | c.702G>A p.P234= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs202059602, COSV99708831; called by muse, mutect2, varscan2
- HEMGN | c.324T>C p.T108= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV99412318; called by muse, mutect2, varscan2
- OR12D3 | c.81G>T p.G27= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV65828797; called by muse, mutect2, varscan2
- PARVA | c.1032G>A p.P344= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs748254467, COSV100616539; called by muse, mutect2, varscan2
- BMPR1B | c.-17-9T>A | Intron (SNP) | VAF 4/43 reads (9%) | called by muse, mutect2
- GABPAP | n.1285C>A | RNA (SNP) | VAF 16/39 reads (41%) | called by muse, mutect2, varscan2
